Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A5DW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A5DW-01A (Primary Tumor).

[page 1 of 2]
Sex: Female

MRN #:
Ref Phy

ICD-6-3
Adenocarcinoma, endometrioid
8380/3
Site: Endometrium C54.1
gw 1/2/13

SPECIMEN IN

Received
Reported:

SURGICAL PATHOLOGY REPORT

*** ADDENDUM REPORT ***

ADDENDUM REPORT ONE:

Results of immunohistochemical staining for DNA mismatch repair enzyme protein expression:

MLH1: intact
PMS2: intact
MSH2: intact
MSH6: intact

IHC control slides stain appropriately

The immunohistochemical study of DNA mismatch repair protein expression reveals presence of MLH1, MSH2, MSH6 and PMS2 expression in the tumor (internal controls stain appropriately). The findings do not completely exclude underlying Lynch Syndrome since some mutations may result in intact protein expression. If there are strong clinical findings suggesting possible Lynch Syndrome, additional MSI by PCR testing is available and can be ordered on the resection specimen.

Addendum Report Issued By:

DIAGNOSIS

DIAGNOSIS:

A. Lymph nodes, left paraaortic; dissection:
Six benign lymph nodes (0/6).

B. Lymph nodes, right paraaortic; dissection:
Seven benign lymph nodes (0/7).

C. Lymph nodes, left pelvic; dissection:
Seven benign lymph nodes (0/7).

D. Lymph nodes, right pelvic; dissection:
Five benign lymph nodes (0/5).

E. Uterus, cervix, and bilateral adnexa; radical hysterectomy and bilateral salpingo-oophorectomy:

Tumor Characteristics:

1. Histologic type: Endometrioid adenocarcinoma.
2. Histologic grade: FIGO grade 2.
3. Tumor site: Endometrium.
4. Tumor size: 5.2 cm in greatest dimension.
5. Myometrial invasion: Not identified.
6. Involvement of cervix: Not identified.
7. Extent of involvement of other organs: Tumor is confined to uterus.
8. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Margins uninvolved: Cervical, parametrial.
3. Margins involved: None.

Lymph Node Status:

1. See parts A-D

Other:

1. Other significant findings:
- Unremarkable ovaries, fallopian tubes, and cervix.
- Immunohistochemical stains for mismatch repair proteins will be performed and reported in an addendum.
2. pTNM stage: pT1aN0.

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Endometrial cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left periaortic lymph node
- B. Right periaortic lymph node
- C. Left pelvic lymph node
- D. Right pelvic lymph node
- E. Uterus, cervix, BSO

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is received in formalin labeled with the patient's name . The specimen consists of portion of fibroadipose tissue that measures 4.5 x 4.0 x 2.0 cm. Sectioning reveals six possible lymph nodes that measure from 0.5 to 1.8 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: three probable nodes block 1; one probable node bisected in block 2; one probable node bisected in block 3; one probable node bisected in blocks 4 and 5.

B. The second container B is received in formalin labeled with the patient's name The specimen consists of a portion of fibroadipose tissue that measures 5.5 x 4.0 x 1.0 cm. Sectioning reveals six possible lymph nodes measuring from 0.5 to 1.6 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: three probable nodes block 1; one probable node bisected in block 2; one probable node bisected in block 3; one probable node bisected in block 4; one probable node bisected in block 5.

C. The third container C is received in formalin labeled left pelvic. The specimen consists of a portion of fibroadipose tissue that measures 8.9 x 6.5 x 2.5 cm. Sectioning reveals seven possible lymph nodes that measure from 0.5 to 3.5 cm. The lymph nodes are entirely submitted in cassettes labeled follows: two probable nodes block 1; two probable nodes block 2; one probable node sectioned in blocks 3 and 4; one probable node trisected in blocks 5 and 6; one probable node sectioned in blocks 7 through 10.

D. The fourth container D is received in formalin labeled with the patient's name right pelvic. The specimen consists of a portion of fibroadipose tissue that measures 7.0 x 6.5 x 2.5 cm. Sectioning reveals five possible lymph nodes that measure from 0.5 to 3.5 cm. Representative sections are submitted in cassettes labeled as follows: one probable node sectioned in blocks 1 and 2; one probable node bisected in blocks 3 and 4; two probable nodes block 5; one probable node sectioned in blocks 6 through 9.

E. The fifth container E is received in formalin labeled The specimen consists of a uterus with attached cervix, attached bilateral adnexa. The uterus measures 7.5 x 7.5 x 5.2 cm and weighs 139 grams. The serosal surface of the uterus is gray-tan to brown-tan. The serosa has been inked. Sections from the parametrium have been taken. The cervix is 5.0 cm in length and 2.7 cm in diameter. The ectocervix is gray-tan to brown-tan with hemorrhage. The endometrial cavity measures 5.0 cm in length and 3.5 cm from cornu to cornu. The lining measures 0.2 cm. There is a gray-brown, slightly hemorrhagic shaggy exophytic mass measuring 5.2 x 2.7 cm that comes within 0.5 cm of the lower uterine segment. On sectioning, the mass extends superficially into the underlying myometrium approximately 0.2 cm into a 1.7 cm thick myometrium. There are no lesions identified. The left ovary measures 2.5 x 2.0 x 1.5 cm. The surface is yellow to gray-tan. On sectioning, there is corpus albicans measuring up to 0.5 cm. The left fallopian tube measures 3.5 cm in length and 0.3 cm in diameter. The surface is gray-tan to brown-tan. On sectioning, there is no material or lesions identified within the lumen. The fallopian tube appears grossly unremarkable. Received with the specimen are three cassettes, one yellow, one green, one blue labeled Representative sections are submitted in cassettes labeled as follows: anterior cervix block 1; posterior cervix block 2; full thickness sections taken from the lesion bisected as follows - one cross section in blocks 3 and 4; one cross section in blocks 5 and 6; one cross section in blocks 7 and 8; one cross section in blocks 9 and 10; one cross section in blocks 11 and 12; lower uterine segment block 13; left parametrium block 14; right parametrium block 15; left ovary block 16; left fallopian tube and paratubal cyst in block 17; right ovary block 18; right fallopian tube block 19.

IIHAA Discrepancy		✓
Case is closed	QUANTIFIED	

Source: NCI Genomic Data Commons file 2cc65c63-1d69-4e0d-a30d-54ace8a2f08e (TCGA-AJ-A5DW.8B641F9B-ACF5-448B-9AC3-8C8E6B1F0724.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).